TARGET case TARGET-40-NAAHBL — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/29060717-657c-515e-9ad0-ab2fb3d9c253

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; Tissue or organ of origin: Bone, NOS; Site of resection or biopsy: Long bones of lower limb and associated joints; Age at diagnosis: 15.9 years (5,806 days); Year of diagnosis: 1999; Days to last follow up: 1,846 days (5.1 years).

Biospecimens (2 samples)
- Sample TARGET-40-NAAHBL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHBL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
